Gene-level copy-number profile of tumor specimen ALCH-B2YG-TTP1-A from ALCHEMIST case ALCH-B2YG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.0 years (28,841 days).
Specimen ALCH-B2YG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c4b92f30-aeb2-47d4-bb27-b74d2b36e1fd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2YG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,796 have no estimate.
https://portal.gdc.cancer.gov/files/d7d0f383-c3b5-4f0e-a765-d96d7c27f6a0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 348; copy number 1: 15,947; copy number 2: 38,223; copy number 3: 3,010; copy number 4: 959; copy number 5: 138; copy number 6: 50; copy number 7: 59; copy number 8: 23; copy number 9: 28; copy number 10: 39; copy number 11: 2; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 124 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,525,187–43,623,666, 1 gene: PTPRF.
- chr1:243,049,782–243,056,394, 2 genes (within-gene range 0–2): CICP21, AL606534.4.
- chr2:232,442,034–232,447,418, 1 gene: DIS3L2P1.
- chr4:1,356,581–1,359,461, 2 genes (within-gene range 0–2): AC078852.2, AC078852.1.
- chr8:22,106,874–22,212,326, 8 genes: NUDT18, HR, REEP4, LGI3, SFTPC, BMP1, AC105206.1, AC105206.3.
- chr9:21,802,636–23,438,700, 20 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr9:61,642,383–61,662,690, 2 genes: Y_RNA, AL935212.1.
- chr9:128,818,500–128,829,794, 2 genes: ENDOG, SPOUT1.
- chr9:131,009,174–131,094,473, 2 genes: LAMC3, AL583807.1.
- chr11:32,435,738–32,440,383, 6 genes (within-gene range 0–2): AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4.
- chr12:109,573,255–109,773,508, 4 genes (within-gene range 0–1): MVK, RN7SKP250, FAM222A, FAM222A-AS1.
- chr14:105,486,317–105,499,575, 3 genes: CRIP1, AL928654.3, TEDC1.
- chr15:25,174,927–25,278,409, 48 genes (within-gene range 0–1): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1, SNORD115-45, SNORD115-46, SNORD115-47, SNORD115-48, SNORD109B.
- chr15:90,839,641–90,963,125, 10 genes: AC124248.1, RN7SL363P, FURIN, FES, MAN2A2, AC068831.3, HDDC3, UNC45A, RCCD1-AS1, RCCD1.
- chr16:5,010,909–5,043,999, 2 genes (within-gene range 0–2): NAGPA-AS1, NAGPA.
- chr16:50,292,616–50,292,675, 1 gene (within-gene range 0–2): MIR6771.
- chr22:41,205,282–41,286,187, 5 genes (within-gene range 0–1): L3MBTL2, L3MBTL2-AS1, CHADL, RANGAP1, MIR6889.
- chr22:42,500,568–42,512,560, 1 gene (within-gene range 0–1): SERHL.
- chr22:46,112,749–46,113,768, 3 genes (within-gene range 0–1): MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 340 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,134–73,865, 5 genes, copy number 9 (within-gene range 2–9): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.
- chr9:61,190,003–61,453,030, 7 genes, copy number 5: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:64,878,790–64,889,063, 2 genes, copy number 11: AC125634.1, RNU6-1293P.
- chr12:66,023,620–67,069,162, 18 genes, copy number 5–8 (within-gene range 4–8): MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4.
- chr12:67,424,272–74,728,851, 123 genes, copy number 5–7 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 3 genes, copy number 5–8: CR383658.1, CR383658.2, BNIP3P6.
- chr16:560,394–565,529, 1 gene, copy number 12: PRR35.
- chr16:32,188,333–32,255,922, 6 genes, copy number 5–7: AC133485.5, AC133485.4, ABHD17AP8, AC133485.1, AC133485.3, TP53TG3D.
- chr18:45,034–4,455,307, 97 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr18:5,895,745–6,415,237, 2 genes, copy number 6 (within-gene range 2–6): AP001021.3, L3MBTL4.
- chr18:6,256,747–6,374,425, 2 genes, copy number 6: L3MBTL4-AS1, MIR4317.
- chr18:6,727,053–7,135,819, 12 genes, copy number 5: AP005205.3, AP005205.2, ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2.
- chr18:8,609,437–11,149,569, 60 genes, copy number 5–9: RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1, PPP4R1-AS1, RNU6-903P, KRT18P8, RAB31, AP000902.1, ZNF415P1, RN7SL862P, AC006238.2, RNA5SP449, PIGPP4, TXNDC2, AC006238.1, VAPA, RNA5SP450, AP005271.1, AP005209.2, AP005209.1, AP006219.1, LINC01254, AP006219.3, APCDD1, NAPG, AP001099.1, LINC01887, AP001180.3, CCDC58P1, AP001180.2, AP001180.5, PMM2P1, AP001180.1, PIEZO2, AP001180.4, KIAA0895LP1, MIR6788, AP005120.1.
- chr21:12,999,676–13,016,692, 1 gene, copy number 5: AP001464.1.
- chr21:44,107,373–44,131,181, 1 gene, copy number 10: PWP2.

Autosomal genes at a single copy (total copy number 1): 13,425. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
